CCDI case PBBXRG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/16320b2b-bf35-4d6f-8ff4-eb10ee733eaf

Demographics
Sex at birth: male; Ethnicity: hispanic or latino; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma: ICD-O-3 morphology code: 9350/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.1 years (5,165 days).

Biospecimens (3 samples)
- Sample 0DK83U: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DK840: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DK845: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
